Gene-level copy-number profile of tumor specimen TCGA-CC-A7IE-01A from TCGA case TCGA-CC-A7IE, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 57.5 years (20,985 days).
Specimen TCGA-CC-A7IE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.e611ecec-2c45-404e-8169-41df6b32d9f2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CC-A7IE-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5d145c0d-78b2-4434-91b6-20db9950ced8

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 247; copy number 2: 9,105; copy number 3: 22,824; copy number 4: 16,791; copy number 5: 4,547; copy number 6: 3,948; copy number 7: 1,283; copy number 8: 774; copy number 9: 301.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CC-A7IE-01A-21D-A381-01): tumor purity 0.43, ploidy 3.54, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,358 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:162,486,541–198,222,513, 645 genes, copy number 7 (broad region; genes not listed).
- chr6:167,607–8,760,447, 178 genes, copy number 7 (broad region; genes not listed).
- chr6:8,653,558–8,653,797, 1 gene, copy number 7: AL161437.1.
- chr8:46,028,804–145,066,685, 1,534 genes, copy number 7–9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 240. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
